Somatic mutation profile of tumor specimen MP2PRT-PAUMET-TMP1-A (aliquot MP2PRT-PAUMET-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUMET, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.0 years (1,819 days).
Specimen MP2PRT-PAUMET-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e959d0a2-8d26-41e7-a207-21f717848abb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMET-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMET-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acf706aa-a905-48a6-b63f-9291ae8f824e

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 94/262 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RYR1 | c.3535C>T p.R1179W | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763944786, CM123704; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACKR3 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 131/281 reads (47%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.636); catalogued as rs142866883; called by muse, mutect2, varscan2
- CCDC150 | c.3239G>T p.R1080L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV99777537; called by muse, mutect2, varscan2
- DIRAS2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1564017915; called by muse, mutect2
- IGSF3 | c.1801G>T p.D601Y (on ENST00000369486 / NM_001007237.3; = p.D621Y on NM_001542.4) | Missense Mutation (SNP) | VAF 155/367 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAN2B2 | c.1824_1825insGG p.R609Gfs*6 | Frame Shift Ins (INS) | VAF 26/307 reads (8%) | called by mutect2, pindel*
- RBM3 | c.376G>C p.G126R | Missense Mutation (SNP) | VAF 108/574 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SSU72P3 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 109/336 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STMN4 | c.334C>A p.L112I (on ENST00000265770 / NM_001283054.2; = p.L139I on NM_030795.4) | Missense Mutation (SNP) | VAF 205/339 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- CASC3 | c.1698G>A p.P566= | Silent (SNP) | VAF 90/364 reads (25%) | catalogued as rs753482185, COSV52869208; called by muse, varscan2
- FYCO1 | c.2925G>T p.L975= | Silent (SNP) | VAF 149/382 reads (39%) | called by muse, mutect2, varscan2
- HOXB3 | c.765G>A p.S255= | Silent (SNP) | VAF 141/525 reads (27%) | catalogued as COSV100290463; called by muse, mutect2, varscan2
- ZFP42 | c.678C>T p.F226= | Silent (SNP) | VAF 78/269 reads (29%) | catalogued as rs754892437, COSV58817528; called by muse, mutect2, varscan2
